RC case RC-B55A — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/eea34232-c7bc-4886-9436-6235b5bf9f0b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1945; Vital status: Dead; Days to death: 6,279 days (17.2 years); Year of death: 2019; Cause of death: Not Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Peripheral T-cell lymphoma, NOS: ICD-O-3 morphology code: 9702/3; ICD-10 code: C84; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Spleen; Classification of tumor: primary; Age at diagnosis: 57.2 years (20,882 days); Year of diagnosis: 2002; Method of diagnosis: Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann arbor b symptoms described array: Weight Loss; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Bone marrow / Spleen.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Etoposide + Ifosfamide; Initial disease status: Initial Diagnosis; Regimen or line of therapy: ICE; Days to treatment start: 195 days; Days to treatment end: 301 days; Number of cycles: 5; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, NOS.

Follow-up (2 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80.
- Day 6,279 (end of treatment course 1): Disease response: Tumor Free; Imaging type: PET; Imaging result: Positive.

Molecular and laboratory tests
- Lactate Dehydrogenase 395 U/L [Blood test normal range upper: 200].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Skin Rash.
- Timepoint category: Initial Diagnosis; Weight: 83.9 kg; Height: 173.7 cm; BMI: 27.8.
- Timepoint category: Prior to Diagnosis; Comorbidities: COPD / Coronary Artery Disease / Diet Controlled Diabetes / Hypertension / Rheumatologic Disease.

Exposures
- Tobacco smoking status: Smoker at Diagnosis; Pack years smoked: 112; Tobacco smoking onset year: 1959; Tobacco smoking quit year: 2016.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B55A-NM1-A: Tissue type: Normal; Specimen type: Bone Marrow Components NOS; Preservation method: Frozen.
- Sample RC-B55A-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B55A-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 80; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
